Somatic mutation profile of cancer-model specimen HCM-CSHL-0091-C25-85A (3D Organoid; aliquot HCM-CSHL-0091-C25-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0091-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.1 years (23,060 days).
Specimen HCM-CSHL-0091-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c83a4dee-1666-4536-afc5-a6e2b1893e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0091-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0091-C25-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d300146-4dea-495a-acf7-73a2f82bf308

The open-access MAF lists 61 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Intron 5, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, Frame Shift Del 1, In Frame Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>G p.V640G (on ENST00000288602 / NM_001374244.1; = p.V600G on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/139 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 30/968 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1280211233; called by muse, mutect2
- ATM | c.8180T>C p.V2727A | Missense Mutation (SNP) | VAF 139/140 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs1565543359, COSV53738015; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNA9 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771575848; called by muse, mutect2, varscan2
- DDX39A | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 108/198 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs958199625; called by muse, mutect2, varscan2
- DMGDH | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 136/220 reads (62%) | catalogued as COSV54861629; called by muse, mutect2, varscan2
- DNAH10 | c.5621G>A p.R1874Q (on ENST00000409039; = p.R1813Q on NM_207437.3) | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750791771; called by muse, mutect2, varscan2
- ITGA7 | c.2311C>T p.R771W (on ENST00000555728; = p.R727W on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/510 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs755674131, COSV57691858; called by muse, mutect2
- PRDM9 | c.242T>C p.I81T | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.122); catalogued as rs1332416989; called by muse, mutect2, varscan2
- PSMD14 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 91/149 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.457); catalogued as COSV68833511; called by muse, mutect2, varscan2
- PTPRJ | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 87/88 reads (99%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs770381504; called by muse, mutect2, varscan2
- RPL11 | c.350A>G p.K117R (on ENST00000374550 / NM_001199802.1; = p.K118R on NM_000975.5) | Missense Mutation (SNP) | VAF 188/189 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.303); catalogued as rs773506948, COSV65778357; called by muse, mutect2, varscan2
- SCTR | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs146299407; called by muse, mutect2, varscan2
- VWF | c.2695G>A p.G899S | Missense Mutation (SNP) | VAF 71/333 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.457); catalogued as rs142135013; called by muse, mutect2, varscan2
- ZNF610 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs751177289; called by muse, mutect2, varscan2
- CNTNAP4 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- CPEB2 | c.603_627delinsTCCGCCGCTCCACTGCCCCGGTCGGTTCAGCCCG p.L202_S209delinsPPLHCPGRFSP | In Frame Ins (INS) | VAF 4/35 reads (11%) | called by pindel, varscan2*
- DDX5 | c.934A>G p.N312D | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DPP6 | c.1222C>T p.L408F (on ENST00000377770 / NM_001364500.2; = p.L346F on NM_001936.5) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- DPY19L4 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- HCN1 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- IFT172 | c.4306A>T p.K1436* | Nonsense Mutation (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- IGF1R | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 127/207 reads (61%) | SIFT tolerated (0.62); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KCNJ15 | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- KCNJ8 | c.939C>A p.Y313* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- LRRCC1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by mutect2, varscan2
- MGMT | c.604C>T p.H202Y (on ENST00000306010; = p.H171Y on NM_002412.5) | Missense Mutation (SNP) | VAF 74/265 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- MOCS1 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.232); called by muse, mutect2
- OLFM3 | c.890del p.V297Afs*53 (on ENST00000338858 / NM_001288821.1; = p.V277Afs*53 on NM_058170.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | called by mutect2, pindel, varscan2
- PLCH1 | c.259G>C p.G87R (on ENST00000340059 / NM_001130960.2; = p.G99R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/263 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PLD1 | c.1327C>G p.P443A | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PRAMEF17 | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 23/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RPRML | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.117); called by muse, mutect2
- SVOP | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- TAOK1 | c.2923G>T p.G975W | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- VMA21 | c.274T>G p.S92A | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2
- BOK | c.378G>C p.L126= | Silent (SNP) | VAF 11/167 reads (7%) | called by muse, mutect2
- CCDC6 | c.786C>T p.I262= | Silent (SNP) | VAF 55/90 reads (61%) | called by muse, mutect2, varscan2
- CRYBG1 | c.2916C>G p.S972= | Silent (SNP) | VAF 138/139 reads (99%) | called by muse, mutect2, varscan2
- FAM47B | c.1026C>A p.S342= | Silent (SNP) | VAF 83/195 reads (43%) | catalogued as COSV100264272; called by muse, mutect2, varscan2
- FXYD5 | c.36C>A p.I12= | Silent (SNP) | VAF 164/585 reads (28%) | called by muse, mutect2, varscan2
- GTF2IRD2 | c.2316A>G p.G772= | Silent (SNP) | VAF 37/136 reads (27%) | called by mutect2, varscan2
- HOXC5 | c.384C>T p.P128= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- IRGC | c.1050G>A p.S350= | Silent (SNP) | VAF 232/392 reads (59%) | catalogued as rs374269776; called by muse, mutect2, varscan2
- MYH7 | c.2988G>A p.K996= | Silent (SNP) | VAF 96/472 reads (20%) | catalogued as rs1176423898; ClinVar: likely benign; called by muse, mutect2, varscan2
- RASL10B | c.408C>T p.R136= | Silent (SNP) | VAF 13/217 reads (6%) | called by muse, mutect2
- SSTR4 | c.321C>T p.A107= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs1410160924, COSV54798060; called by muse, mutect2, varscan2
- UBAP1L | c.783G>A p.A261= | Silent (SNP) | VAF 22/240 reads (9%) | catalogued as rs185974312; called by muse, mutect2
- ZNF862 | c.3150G>A p.R1050= | Silent (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2
- AKR1B10 | c.742-31A>G | Intron (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- CLDN5 | chr22:19524460 C>T | 5'Flank (SNP) | VAF 13/14 reads (93%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.231-4543A>G | Intron (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- CT45A3 | c.*71A>T | 3'UTR (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2
- CTRB2 | c.-15C>T | 5'UTR (SNP) | VAF 249/407 reads (61%) | called by muse, mutect2, varscan2
- MATR3 | c.*1542C>T | 3'UTR (SNP) | VAF 35/114 reads (31%) | catalogued as rs925752471; called by muse, mutect2, varscan2
- PRSS1 | c.200+382A>C | Intron (SNP) | VAF 58/96 reads (60%) | called by muse, varscan2
- UBR3 | c.3634+5868G>A | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs1220739165, COSV55855122; called by mutect2, varscan2
- VSTM2L | c.-1G>C | 5'UTR (SNP) | VAF 64/303 reads (21%) | called by muse, mutect2, varscan2
- ZNF429 | chr19:21541836 C>T | 3'Flank (SNP) | VAF 10/23 reads (43%) | catalogued as rs538414617; called by muse, mutect2, varscan2
- ZNF513 | c.56-38T>G | Intron (SNP) | VAF 57/103 reads (55%) | called by muse, mutect2, varscan2
